Somatic mutation profile of tumor specimen ALCH-B1YB-TTP1-A (aliquot ALCH-B1YB-TTP1-A-1-0-D-A76I-36) from ALCHEMIST case ALCH-B1YB, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 57.1 years (20,841 days).
Specimen ALCH-B1YB-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) efc219af-4724-43a6-bcbe-a8db009adc87.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1YB-NB1-A (Blood Derived Normal), aliquot ALCH-B1YB-NB1-A-1-0-D-A76I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9910ffb2-5315-4578-8fd0-f0c33bd72c33

The open-access MAF lists 280 somatic variants for this specimen: 197 protein-altering or splice-affecting, 52 silent, 31 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 165, Silent 52, Nonsense Mutation 16, Intron 13, Splice Site 7, RNA 6, Frame Shift Del 6, 3'UTR 6, 5'Flank 3, Splice Region 3, 5'UTR 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PRRT2 | c.649del p.R217Efs*12 | Frame Shift Del (DEL) | VAF 9/57 reads (16%) | catalogued as rs587778771; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- SGCB | c.243+1G>T p.X81_splice | Splice Site (SNP) | VAF 22/522 reads (4%) | catalogued as rs1553940663; ClinVar: likely pathogenic; called by muse, mutect2
- ADAMTS16 | c.1942C>A p.R648S | Missense Mutation (SNP) | VAF 38/404 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57001543; called by muse, mutect2
- ADAMTS20 | c.3747A>C p.E1249D | Missense Mutation (SNP) | VAF 55/778 reads (7%) | SIFT tolerated (0.94); PolyPhen benign (0.059); catalogued as COSV101166424; called by muse, mutect2
- AGBL4 | c.1057G>T p.A353S | Missense Mutation (SNP) | VAF 14/511 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as COSV61890645; called by muse, mutect2
- ANO1 | c.1490C>A p.A497E | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.069); catalogued as COSV100304544; called by muse, mutect2
- CACNA1G | c.69C>A p.N23K | Missense Mutation (SNP) | VAF 36/496 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as rs1444589414; called by muse, mutect2
- CCDC168 | c.815A>T p.Q272L | Missense Mutation (SNP) | VAF 19/269 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1208328727; called by muse, mutect2
- CDH19 | c.232C>G p.Q78E | Missense Mutation (SNP) | VAF 6/125 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as COSV50973586; called by muse, mutect2
- CNTNAP2 | c.1870C>A p.P624T | Missense Mutation (SNP) | VAF 55/696 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV62150646; called by muse, mutect2
- CRACD | c.85C>A p.Q29K | Missense Mutation (SNP) | VAF 19/308 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99949056; called by muse, mutect2
- DOCK2 | c.2154G>C p.K718N | Missense Mutation (SNP) | VAF 10/252 reads (4%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.994); catalogued as COSV56941087; called by muse, mutect2
- EML5 | c.2404G>T p.D802Y | Missense Mutation (SNP) | VAF 54/461 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs758262675; called by muse, mutect2, varscan2
- EPB41L3 | c.2597C>T p.A866V | Missense Mutation (SNP) | VAF 38/920 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as rs749541572; called by muse, mutect2
- EPHA1 | c.2402G>A p.R801Q | Missense Mutation (SNP) | VAF 38/426 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs770181636, COSV51974568; called by muse, mutect2
- EPHA3 | c.100G>C p.D34H | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60733615; called by muse, mutect2
- FCGBP | c.11200G>T p.A3734S | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.121); catalogued as rs777554353; called by muse, mutect2
- FCGBP | c.1495G>T p.V499L | Missense Mutation (SNP) | VAF 39/549 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.137); catalogued as rs1330081304; called by muse, mutect2
- FMO2 | c.712C>T p.R238W | Missense Mutation (SNP) | VAF 90/1170 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs371234521, COSV99268877; called by muse, mutect2
- HACE1 | c.2442+1G>T p.X814_splice | Splice Site (SNP) | VAF 22/293 reads (8%) | catalogued as COSV53504964; called by muse, mutect2
- HCAR3 | c.579C>A p.F193L | Missense Mutation (SNP) | VAF 39/517 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs762905221; called by muse, mutect2
- IL10 | c.166-1G>A p.X56_splice | Splice Site (SNP) | VAF 70/781 reads (9%) | catalogued as rs759551600; called by muse, mutect2
- INTS1 | c.217G>T p.G73C | Missense Mutation (SNP) | VAF 32/316 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.734); catalogued as rs1009068667, COSV67180158; called by muse, mutect2
- IQGAP3 | c.3359G>T p.R1120L | Missense Mutation (SNP) | VAF 32/381 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.434); catalogued as COSV63252251; called by muse, mutect2
- KEAP1 | c.1237C>T p.R413C | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1178941219, COSV99407588; called by muse, mutect2, varscan2
- KPRP | c.1352G>T p.R451L | Missense Mutation (SNP) | VAF 36/442 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.357); catalogued as rs755668740, COSV64222581; called by muse, mutect2
- LAMA1 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 31/728 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67537490; called by muse, mutect2
- LRRTM4 | c.248G>T p.G83V | Missense Mutation (SNP) | VAF 52/882 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV101297723, COSV69142957; called by muse, mutect2
- LRRTM4 | c.247G>T p.G83C | Missense Mutation (SNP) | VAF 52/882 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV69138812, COSV69141526; called by muse, mutect2
- MTA1 | c.311G>T p.R104L | Missense Mutation (SNP) | VAF 23/384 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as COSV58756372; called by muse, mutect2
- MYO18B | c.6895G>A p.G2299R | Missense Mutation (SNP) | VAF 4/75 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.044); catalogued as COSV100125723; called by muse, mutect2
- NEU4 | c.1160G>C p.R387T (on ENST00000391969 / NM_001167602.3; = p.R399T on NM_080741.4) | Missense Mutation (SNP) | VAF 13/291 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.062); catalogued as COSV57991793; called by muse, mutect2
- NHSL2 | c.1912G>T p.V638L (on ENST00000510661; = p.V1004L on NM_001013627.2) | Missense Mutation (SNP) | VAF 71/527 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV65453336; called by muse, mutect2, varscan2
- OBSCN | c.16748C>T p.S5583F | Missense Mutation (SNP) | VAF 31/475 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52832409; called by muse, mutect2
- OR10X1 | c.457A>T p.T153S | Missense Mutation (SNP) | VAF 24/870 reads (3%) | SIFT tolerated (1); PolyPhen probably damaging (0.99); catalogued as COSV100936735; called by muse, mutect2
- OR1A2 | c.46G>T p.G16* | Nonsense Mutation (SNP) | VAF 27/449 reads (6%) | catalogued as COSV101126384; called by muse, mutect2
- OR2G3 | c.802C>A p.Q268K | Missense Mutation (SNP) | VAF 35/611 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV60682928; called by muse, mutect2
- OR4C11 | c.445G>T p.G149W | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100155502; called by muse, mutect2, varscan2
- OR51T1 | c.426G>T p.M142I | Missense Mutation (SNP) | VAF 29/334 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV59024019, COSV59028662; called by muse, mutect2
- OR5M11 | c.168C>A p.H56Q | Missense Mutation (SNP) | VAF 89/768 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.034); catalogued as COSV73141721; called by muse, mutect2, varscan2
- OR7A5 | c.20C>A p.T7K | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV59234936; called by muse, varscan2
- PCDH10 | c.1864C>A p.R622S | Missense Mutation (SNP) | VAF 24/548 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52091616; called by muse, mutect2
- PCDHGA7 | c.2149C>T p.R717W | Missense Mutation (SNP) | VAF 36/944 reads (4%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.082); catalogued as rs1015626472, COSV53922923; called by muse, mutect2
- POLR3A | c.925G>T p.D309Y | Missense Mutation (SNP) | VAF 118/1166 reads (10%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.748); catalogued as COSV100965686; called by muse, mutect2, varscan2
- RIMBP2 | c.76C>A p.Q26K | Missense Mutation (SNP) | VAF 16/282 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV55473272, COSV55485497; called by muse, mutect2
- RYR2 | c.5880G>T p.R1960S | Missense Mutation (SNP) | VAF 23/294 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.293); catalogued as COSV63669081; called by muse, mutect2
- SEMA6A | c.2635C>A p.P879T | Missense Mutation (SNP) | VAF 42/518 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1273537361; called by muse, mutect2
- SEPTIN12 | c.725G>C p.R242P | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51615739, COSV51615778; called by muse, mutect2, varscan2
- TMC1 | c.1758G>T p.M586I | Missense Mutation (SNP) | VAF 53/881 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.966); catalogued as COSV52781332; called by muse, mutect2
- TMEM161B | c.1402G>T p.A468S | Missense Mutation (SNP) | VAF 25/225 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV56931393; called by muse, mutect2, varscan2
- TRIM9 | c.1202G>T p.G401V | Missense Mutation (SNP) | VAF 55/792 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV53618984; called by muse, mutect2
- ZNF99 | c.1512G>T p.M504I | Missense Mutation (SNP) | VAF 20/367 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs879248703, COSV68055760; called by muse, mutect2
- ZNRF4 | c.1034G>T p.R345L | Missense Mutation (SNP) | VAF 36/253 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as COSV55775838; called by muse, mutect2, varscan2
- ABCC11 | c.775G>T p.E259* | Nonsense Mutation (SNP) | VAF 20/276 reads (7%) | called by muse, mutect2
- ACP7 | c.1184A>G p.Y395C | Missense Mutation (SNP) | VAF 40/680 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- ACSF2 | c.510G>T p.V170= | Splice Region (SNP) | VAF 26/312 reads (8%) | called by muse, mutect2
- ACTL9 | c.1031C>A p.S344Y | Missense Mutation (SNP) | VAF 24/248 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ADAMTSL2 | c.1075G>T p.G359W | Missense Mutation (SNP) | VAF 38/594 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.305); called by muse, mutect2
- ADCY5 | c.2540T>C p.L847P | Missense Mutation (SNP) | VAF 38/274 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ADGRL2 | c.1630A>T p.N544Y | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); called by muse, varscan2
- AGBL4 | c.1056G>T p.Q352H | Missense Mutation (SNP) | VAF 14/520 reads (3%) | SIFT tolerated (0.7); PolyPhen benign (0.103); called by muse, mutect2
- AMER2 | c.1513G>T p.E505* | Nonsense Mutation (SNP) | VAF 22/417 reads (5%) | called by muse, mutect2
- ANK2 | c.7602C>A p.S2534R | Missense Mutation (SNP) | VAF 42/479 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ANKK1 | c.165C>A p.C55* | Nonsense Mutation (SNP) | VAF 9/149 reads (6%) | called by muse, mutect2
- APAF1 | c.2291A>T p.D764V (on ENST00000551964 / NM_181861.2; = p.D753V on NM_001160.3) | Missense Mutation (SNP) | VAF 21/539 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ATM | c.2255T>C p.L752P | Missense Mutation (SNP) | VAF 16/310 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- ATP2A1 | c.749A>G p.Q250R | Missense Mutation (SNP) | VAF 44/584 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); called by muse, mutect2
- ATP6V1C2 | c.1237T>A p.Y413N (on ENST00000272238 / NM_001039362.2; = p.Y367N on NM_144583.4) | Missense Mutation (SNP) | VAF 39/412 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BRINP3 | c.580A>G p.R194G | Missense Mutation (SNP) | VAF 37/940 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.131); called by muse, mutect2
- C10orf82 | c.274+8C>A | Splice Region (SNP) | VAF 11/127 reads (9%) | called by muse, mutect2
- C11orf87 | c.82A>C p.S28R | Missense Mutation (SNP) | VAF 84/981 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); called by muse, mutect2
- CCDC168 | c.19589G>T p.S6530I | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- CCDC171 | c.3473G>C p.R1158T | Missense Mutation (SNP) | VAF 8/155 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.203); called by muse, mutect2
- CCDC58 | c.229C>T p.Q77* | Nonsense Mutation (SNP) | VAF 35/510 reads (7%) | called by muse, mutect2
- CCNB3 | c.2503G>T p.E835* | Nonsense Mutation (SNP) | VAF 110/1153 reads (10%) | called by muse, mutect2
- CELSR2 | c.493G>T p.E165* | Nonsense Mutation (SNP) | VAF 15/372 reads (4%) | called by muse, mutect2
- CHD5 | c.1720C>A p.L574I | Missense Mutation (SNP) | VAF 64/413 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- COL3A1 | c.2146C>T p.P716S | Missense Mutation (SNP) | VAF 78/1456 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.006); called by muse, mutect2
- CRYBA4 | c.418G>T p.G140W | Missense Mutation (SNP) | VAF 39/374 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CRYBA4 | c.419G>T p.G140V | Missense Mutation (SNP) | VAF 38/370 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CRYZL1 | c.1030A>G p.K344E | Missense Mutation (SNP) | VAF 11/276 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.272); called by muse, mutect2
- CSRNP2 | c.150A>T p.T50= | Splice Region (SNP) | VAF 10/172 reads (6%) | called by muse, mutect2
- CSRP2 | c.491A>T p.E164V | Missense Mutation (SNP) | VAF 9/169 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2
- CYP4F11 | c.985G>T p.G329C | Missense Mutation (SNP) | VAF 48/397 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DLG5 | c.1680G>C p.E560D | Missense Mutation (SNP) | VAF 32/398 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.009); called by muse, mutect2
- DNAH7 | c.9087G>T p.Q3029H | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DPYD | c.748G>T p.D250Y | Missense Mutation (SNP) | VAF 50/431 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- EFHD2 | c.406A>G p.M136V | Missense Mutation (SNP) | VAF 26/185 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- EIF4A3 | c.995T>C p.I332T | Missense Mutation (SNP) | VAF 14/296 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ELF5 | c.487C>A p.H163N (on ENST00000312319 / NM_198381.2; = p.H153N on NM_001422.4) | Missense Mutation (SNP) | VAF 54/388 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EYA2 | c.110-1G>A p.X37_splice | Splice Site (SNP) | VAF 52/611 reads (9%) | called by muse, mutect2
- FARSB | c.1537G>T p.G513W | Missense Mutation (SNP) | VAF 12/278 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GCC1 | c.323C>T p.T108I | Missense Mutation (SNP) | VAF 84/787 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- GCM2 | c.1262C>A p.T421N | Missense Mutation (SNP) | VAF 85/646 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- GLI2 | c.3218G>T p.S1073I (on ENST00000361492 / NM_001374353.1; = p.S1090I on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/600 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- GLO1 | c.373T>A p.F125I | Missense Mutation (SNP) | VAF 45/417 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GNAL | c.417del p.K139Nfs*8 (on ENST00000269162 / NM_001142339.3; = p.K216Nfs*8 on NM_182978.4) | Frame Shift Del (DEL) | VAF 45/422 reads (11%) | called by mutect2, pindel, varscan2
- GPR34 | c.1082C>A p.P361Q | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2
- GPR37 | c.570G>T p.Q190H | Missense Mutation (SNP) | VAF 78/752 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GRIN2B | c.3590G>T p.W1197L | Missense Mutation (SNP) | VAF 22/408 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0.173); called by muse, mutect2
- GRM5 | c.1278T>A p.C426* | Nonsense Mutation (SNP) | VAF 74/894 reads (8%) | called by muse, mutect2
- GRM6 | c.2455A>G p.T819A | Missense Mutation (SNP) | VAF 32/842 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); called by muse, mutect2
- GYG2 | c.623C>G p.S208W | Missense Mutation (SNP) | VAF 55/592 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); called by muse, mutect2
- HABP4 | c.735A>T p.K245N | Missense Mutation (SNP) | VAF 24/429 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.958); called by muse, mutect2
- HACE1 | c.2442G>T p.Q814H | Missense Mutation (SNP) | VAF 22/296 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2
- HAPLN1 | c.764C>A p.S255Y | Missense Mutation (SNP) | VAF 9/125 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2
- HAS2 | c.1495G>T p.E499* | Nonsense Mutation (SNP) | VAF 63/314 reads (20%) | called by muse, mutect2, varscan2
- HECTD4 | c.8452G>C p.V2818L | Missense Mutation (SNP) | VAF 18/276 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2
- HECW2 | c.4488G>T p.L1496F | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HERC2 | c.12403A>T p.K4135* | Nonsense Mutation (SNP) | VAF 6/116 reads (5%) | called by muse, mutect2
- HGF | c.1181G>T p.G394V | Missense Mutation (SNP) | VAF 42/734 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); called by muse, mutect2
- HMCN2 | c.14191G>A p.E4731K | Missense Mutation (SNP) | VAF 15/202 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.35); called by muse, mutect2
- HOXA3 | c.1226A>T p.H409L | Missense Mutation (SNP) | VAF 22/364 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.412); called by muse, mutect2
- ITGA8 | c.2056G>T p.A686S | Missense Mutation (SNP) | VAF 14/259 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); called by muse, mutect2
- KEL | c.2168T>G p.L723W | Missense Mutation (SNP) | VAF 20/637 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2
- KRT25 | c.549G>T p.E183D | Missense Mutation (SNP) | VAF 66/757 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.533); called by muse, mutect2
- LCT | c.5652G>C p.L1884F | Missense Mutation (SNP) | VAF 33/755 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); called by muse, mutect2
- LNX2 | c.1269A>T p.K423N | Missense Mutation (SNP) | VAF 32/278 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- LOXHD1 | c.1136T>A p.V379E | Missense Mutation (SNP) | VAF 20/481 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MAGEC2 | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 50/540 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.258); called by muse, mutect2
- MAGI3 | c.2492G>C p.G831A | Missense Mutation (SNP) | VAF 31/546 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.797); called by muse, mutect2
- MAP3K19 | c.1754G>T p.W585L | Missense Mutation (SNP) | VAF 29/270 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- MEGF8 | c.4237G>T p.G1413W (on ENST00000251268 / NM_001271938.2; = p.G1346W on NM_001410.3) | Missense Mutation (SNP) | VAF 25/409 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- MEGF8 | c.4238G>T p.G1413V (on ENST00000251268 / NM_001271938.2; = p.G1346V on NM_001410.3) | Missense Mutation (SNP) | VAF 25/416 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.51); called by muse, mutect2
- MGAM2 | c.5803G>T p.A1935S | Missense Mutation (SNP) | VAF 16/224 reads (7%) | SIFT tolerated, low confidence (0.45); called by muse, mutect2
- MMP20 | c.485C>A p.S162* | Nonsense Mutation (SNP) | VAF 84/970 reads (9%) | called by muse, mutect2
- MROH2A | c.977A>T p.Q326L | Missense Mutation (SNP) | VAF 26/515 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2
- MSTN | c.712G>T p.A238S | Missense Mutation (SNP) | VAF 17/222 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); called by muse, mutect2
- MTMR2 | c.1235C>T p.S412F | Missense Mutation (SNP) | VAF 65/827 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MUC16 | c.15325A>T p.K5109* | Nonsense Mutation (SNP) | VAF 31/216 reads (14%) | called by muse, mutect2, varscan2
- MXRA5 | c.4331C>A p.S1444* | Nonsense Mutation (SNP) | VAF 31/311 reads (10%) | called by muse, mutect2, varscan2
- MYH1 | c.655C>A p.L219M | Missense Mutation (SNP) | VAF 50/1172 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- MYH4 | c.519G>C p.Q173H | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- MYO3A | c.3613T>C p.Y1205H | Missense Mutation (SNP) | VAF 19/322 reads (6%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); called by muse, mutect2
- NEO1 | c.2243G>T p.R748L | Missense Mutation (SNP) | VAF 34/368 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2
- NFASC | c.3406G>T p.G1136C (on ENST00000339876 / NM_001378329.1; = p.G1065C on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/367 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NUAK1 | c.1299G>C p.Q433H | Missense Mutation (SNP) | VAF 43/850 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.169); called by muse, mutect2
- NWD2 | c.169C>G p.Q57E | Missense Mutation (SNP) | VAF 9/185 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2
- OR2M3 | c.631G>T p.V211F | Missense Mutation (SNP) | VAF 48/1012 reads (5%) | SIFT tolerated (0.97); PolyPhen benign (0.068); called by muse, mutect2
- OR4A15 | c.724G>T p.V242F | Missense Mutation (SNP) | VAF 27/246 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PAPPA2 | c.481G>T p.G161W | Missense Mutation (SNP) | VAF 68/818 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.761); called by muse, mutect2
- PARP1 | c.2964-2A>T p.X988_splice | Splice Site (SNP) | VAF 72/930 reads (8%) | called by muse, mutect2
- PCDH15 | c.5291T>A p.V1764E | Missense Mutation (SNP) | VAF 58/780 reads (7%) | SIFT deleterious, low confidence (0); called by muse, mutect2
- PCDHB10 | c.1813C>A p.Q605K | Missense Mutation (SNP) | VAF 58/1286 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.685); called by muse, mutect2
- PCDHGA9 | c.1540C>A p.L514M | Missense Mutation (SNP) | VAF 30/306 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- PGBD2 | c.881A>G p.Y294C | Missense Mutation (SNP) | VAF 59/690 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- PHLPP2 | c.784G>T p.E262* | Nonsense Mutation (SNP) | VAF 22/307 reads (7%) | called by muse, mutect2
- PIWIL4 | c.544G>T p.G182C | Missense Mutation (SNP) | VAF 38/404 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- POU1F1 | c.794G>T p.R265L | Missense Mutation (SNP) | VAF 16/415 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PRMT5 | c.911A>G p.Y304C | Missense Mutation (SNP) | VAF 28/239 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- PROX1 | c.303G>T p.M101I | Missense Mutation (SNP) | VAF 16/424 reads (4%) | SIFT tolerated (0.96); PolyPhen benign (0.007); called by muse, mutect2
- PRPS1L1 | c.64del p.R22Afs*6 | Frame Shift Del (DEL) | VAF 196/1521 reads (13%) | called by mutect2, pindel, varscan2
- PRSS58 | c.461C>A p.T154N | Missense Mutation (SNP) | VAF 61/482 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PTER | c.277G>T p.G93W | Missense Mutation (SNP) | VAF 62/762 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PTPRC | c.296C>A p.T99K | Missense Mutation (SNP) | VAF 93/751 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PZP | c.106T>C p.S36P | Missense Mutation (SNP) | VAF 24/490 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.918); called by muse, mutect2
- RAI14 | c.1934T>A p.V645E | Missense Mutation (SNP) | VAF 30/405 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2
- RBM10 | c.2100+1G>T p.X700_splice | Splice Site (SNP) | VAF 71/837 reads (8%) | called by muse, mutect2
- RBP3 | c.3339C>A p.S1113R | Missense Mutation (SNP) | VAF 134/1137 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- RP1L1 | c.6314A>T p.E2105V | Missense Mutation (SNP) | VAF 49/722 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.449); called by muse, mutect2
- RRP12 | c.2245A>T p.T749S | Missense Mutation (SNP) | VAF 14/427 reads (3%) | SIFT tolerated (0.19); PolyPhen benign (0.143); called by muse, mutect2
- SAMD9 | c.4173del p.N1392Tfs*13 | Frame Shift Del (DEL) | VAF 48/482 reads (10%) | called by pindel, varscan2
- SAP30 | c.315C>A p.S105R | Missense Mutation (SNP) | VAF 36/1107 reads (3%) | SIFT tolerated (0.19); PolyPhen benign (0.269); called by muse, mutect2
- SCFD2 | c.1586C>T p.T529I | Missense Mutation (SNP) | VAF 16/470 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- SELL | c.681G>T p.L227F (on ENST00000650983; = p.L214F on NM_000655.5) | Missense Mutation (SNP) | VAF 27/325 reads (8%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.935); called by muse, mutect2
- SNX18 | c.229_230delinsT p.R77Sfs*149 | Frame Shift Del (DEL) | VAF 9/79 reads (11%) | called by pindel, varscan2*
- SPATA20 | c.1529-1G>T p.X510_splice (on ENST00000356488 / NM_001258372.1; = p.X526_splice on NM_022827.4) | Splice Site (SNP) | VAF 6/61 reads (10%) | called by mutect2, varscan2
- SPATA31A3 | c.3514C>T p.Q1172* | Nonsense Mutation (SNP) | VAF 34/1212 reads (3%) | called by muse, mutect2
- SPOCK1 | c.407G>T p.C136F | Missense Mutation (SNP) | VAF 48/912 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- SRRM2 | c.401G>T p.R134I | Missense Mutation (SNP) | VAF 17/418 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- SSR2 | c.169G>T p.V57L | Missense Mutation (SNP) | VAF 38/426 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2
- ST6GAL2 | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 23/236 reads (10%) | PolyPhen benign (0.001); called by muse, mutect2
- STARD6 | c.393T>A p.S131R | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- STYXL2 | c.1062G>T p.W354C | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SYNJ2 | c.3622G>T p.E1208* | Nonsense Mutation (SNP) | VAF 17/249 reads (7%) | called by muse, mutect2
- SYVN1 | c.8G>C p.R3P | Missense Mutation (SNP) | VAF 33/321 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TAF4B | c.1477A>G p.T493A | Missense Mutation (SNP) | VAF 22/676 reads (3%) | SIFT tolerated (0.26); PolyPhen benign (0.057); called by muse, mutect2
- TBXT | c.532C>A p.P178T | Missense Mutation (SNP) | VAF 87/1444 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2
- THSD7B | c.1600T>C p.S534P | Missense Mutation (SNP) | VAF 24/896 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); called by muse, mutect2
- TMEM164 | c.811G>A p.V271I (on ENST00000372068 / NM_032227.4; = p.V122I on NM_017698.2) | Missense Mutation (SNP) | VAF 34/935 reads (4%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2
- TMEM72 | c.500A>T p.Q167L | Missense Mutation (SNP) | VAF 26/512 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.407); called by muse, mutect2
- TMPRSS11F | c.416C>A p.A139D | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0.197); called by muse, mutect2
- TONSL | c.3363del p.L1122Sfs*15 | Frame Shift Del (DEL) | VAF 13/102 reads (13%) | called by mutect2, pindel, varscan2
- TRBV4-1 | c.253C>A p.P85T | Missense Mutation (SNP) | VAF 28/553 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- TRPM6 | c.381G>T p.M127I | Missense Mutation (SNP) | VAF 46/956 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.692); called by muse, mutect2
- TSHZ3 | c.2748G>T p.Q916H | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- UPB1 | c.878A>C p.H293P | Missense Mutation (SNP) | VAF 99/1012 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2
- WDFY4 | c.6218G>T p.R2073I | Missense Mutation (SNP) | VAF 23/309 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2
- ZBTB47 | c.435G>T p.E145D | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); called by muse, mutect2
- ZNF10 | c.1139C>T p.P380L | Missense Mutation (SNP) | VAF 10/145 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2
- ZNF226 | c.1033A>T p.S345C | Missense Mutation (SNP) | VAF 40/531 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.05); called by muse, mutect2
- ZNF324 | c.1130G>T p.R377L | Missense Mutation (SNP) | VAF 18/460 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.471); called by muse, mutect2
- ZNF423 | c.1849G>T p.D617Y (on ENST00000563137 / NM_001379286.1; = p.D609Y on NM_015069.4) | Missense Mutation (SNP) | VAF 33/324 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- ZNF716 | c.23C>A p.P8H | Missense Mutation (SNP) | VAF 60/968 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2
- ZNF730 | c.29C>A p.A10D | Missense Mutation (SNP) | VAF 44/927 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- ZNF841 | c.2000A>C p.H667P (on ENST00000426391 / NM_001369830.1; = p.H783P on NM_001136499.1 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF99 | c.1511T>A p.M504K | Missense Mutation (SNP) | VAF 18/366 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.048); called by muse, mutect2
- ACAP3 | c.1770C>T p.L590= | Silent (SNP) | VAF 30/317 reads (9%) | catalogued as rs368975349; called by muse, mutect2
- ACSF2 | c.1299G>T p.V433= | Silent (SNP) | VAF 36/460 reads (8%) | called by muse, mutect2
- ADGRA1 | c.66C>T p.Y22= | Silent (SNP) | VAF 38/530 reads (7%) | catalogued as rs113359644, COSV66931421; called by muse, mutect2
- CNST | c.591A>G p.A197= | Silent (SNP) | VAF 12/318 reads (4%) | called by muse, mutect2
- COL14A1 | c.570G>T p.V190= | Silent (SNP) | VAF 24/266 reads (9%) | catalogued as rs1229678049; called by muse, mutect2
- CUL4A | c.951G>C p.P317= (on ENST00000375440 / NM_001008895.4; = p.P217= on NM_003589.3) | Silent (SNP) | VAF 33/480 reads (7%) | called by muse, mutect2
- CYP11B1 | c.705C>A p.V235= | Silent (SNP) | VAF 192/1318 reads (15%) | called by muse, mutect2, varscan2
- DDX60 | c.2331G>A p.K777= | Silent (SNP) | VAF 62/524 reads (12%) | called by muse, mutect2, varscan2
- DLGAP2 | c.1881C>A p.I627= | Silent (SNP) | VAF 30/248 reads (12%) | catalogued as rs770930937; called by muse, mutect2, varscan2
- ECPAS | c.5493G>T p.L1831= | Silent (SNP) | VAF 13/271 reads (5%) | called by muse, mutect2
- ECT2L | c.2373C>G p.A791= | Silent (SNP) | VAF 8/130 reads (6%) | called by muse, mutect2
- EMX1 | c.132C>T p.T44= | Silent (SNP) | VAF 20/377 reads (5%) | catalogued as rs1421106399; called by muse, mutect2
- ERICH6B | c.420G>T p.L140= | Silent (SNP) | VAF 88/798 reads (11%) | called by mutect2, varscan2
- FCGBP | c.11199G>T p.V3733= | Silent (SNP) | VAF 7/134 reads (5%) | called by muse, mutect2
- FST | c.580C>A p.R194= | Silent (SNP) | VAF 87/914 reads (10%) | catalogued as COSV56815240; called by muse, mutect2
- GRIA4 | c.372T>A p.T124= | Silent (SNP) | VAF 72/1148 reads (6%) | called by muse, mutect2
- GRID2 | c.900T>G p.R300= | Silent (SNP) | VAF 11/252 reads (4%) | called by muse, mutect2
- GRM6 | c.301C>A p.R101= | Silent (SNP) | VAF 16/242 reads (7%) | called by muse, mutect2
- HAPLN1 | c.765C>A p.S255= | Silent (SNP) | VAF 9/124 reads (7%) | catalogued as COSV57147123; called by muse, mutect2
- HHIPL2 | c.2007G>A p.L669= | Silent (SNP) | VAF 96/1218 reads (8%) | called by muse, mutect2
- KANSL1 | c.3300C>T p.R1100= (on ENST00000574590 / NM_001193465.2; = p.R1101= on NM_015443.4) | Silent (SNP) | VAF 30/274 reads (11%) | called by muse, mutect2
- KDM5A | c.3258C>T p.G1086= | Silent (SNP) | VAF 29/454 reads (6%) | called by muse, mutect2
- KDM5B | c.2760A>G p.L920= | Silent (SNP) | VAF 62/768 reads (8%) | called by muse, mutect2
- KIDINS220 | c.2814C>A p.T938= | Silent (SNP) | VAF 26/702 reads (4%) | called by muse, mutect2
- MED11 | c.63C>T p.I21= | Silent (SNP) | VAF 33/395 reads (8%) | called by muse, mutect2
- MGAT5 | c.1824G>T p.T608= | Silent (SNP) | VAF 32/376 reads (9%) | catalogued as rs545961795; called by muse, mutect2
- MGMT | c.21C>T p.P7= | Silent (SNP) | VAF 36/396 reads (9%) | catalogued as rs1454324309; called by muse, mutect2
- MMD2 | c.645A>T p.G215= (on ENST00000404774 / NM_001100600.2; = p.G191= on NM_198403.4) | Silent (SNP) | VAF 63/611 reads (10%) | called by muse, mutect2, varscan2
- MUC19 | c.156C>T p.A52= | Silent (SNP) | VAF 38/438 reads (9%) | called by muse, mutect2
- NR1I2 | c.1080C>T p.R360= | Silent (SNP) | VAF 61/594 reads (10%) | catalogued as rs574897255; called by muse, mutect2, varscan2
- NRG3 | c.2079C>A p.P693= (on ENST00000404547 / NM_001370084.1; = p.P669= on NM_001010848.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 72/846 reads (9%) | catalogued as rs117760740; called by muse, mutect2
- NRXN3 | c.681A>G p.Q227= (on ENST00000557594 / NM_001272020.2; = p.Q859= on NM_004796.6) | Silent (SNP) | VAF 32/723 reads (4%) | catalogued as rs1376714407; called by muse, mutect2
- NTN1 | c.1272C>A p.P424= | Silent (SNP) | VAF 29/509 reads (6%) | called by muse, mutect2
- OR4C15 | c.1002G>A p.L334= (on ENST00000314644; = p.L280= on NM_001001920.2) | Silent (SNP) | VAF 58/672 reads (9%) | catalogued as rs769561427, COSV100115651, COSV58953273; called by muse, mutect2
- PLXNA4 | c.3967C>A p.R1323= | Silent (SNP) | VAF 42/422 reads (10%) | catalogued as COSV58104969; called by muse, mutect2
- POM121L12 | c.474C>G p.A158= | Silent (SNP) | VAF 16/358 reads (4%) | called by muse, mutect2
- RAVER2 | c.1737C>T p.L579= (on ENST00000294428 / NM_001366165.1; = p.L566= on NM_018211.4) | Silent (SNP) | VAF 16/366 reads (4%) | called by muse, mutect2
- RBM20 | c.3312C>A p.T1104= | Silent (SNP) | VAF 43/411 reads (10%) | called by muse, mutect2, varscan2
- RBM23 | c.708C>A p.I236= (on ENST00000359890 / NM_001077351.2; = p.I220= on NM_018107.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/326 reads (8%) | catalogued as COSV57128730; called by muse, mutect2
- RIMBP2 | c.1689C>A p.T563= | Silent (SNP) | VAF 36/582 reads (6%) | called by muse, mutect2
- RNF168 | c.717A>G p.S239= | Silent (SNP) | VAF 32/803 reads (4%) | called by muse, mutect2
- RPTN | c.714T>C p.S238= | Silent (SNP) | VAF 115/700 reads (16%) | catalogued as rs28455544; called by muse, mutect2, varscan2
- SALL3 | c.420G>T p.G140= | Silent (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- SPAAR | c.138C>T p.A46= | Silent (SNP) | VAF 34/516 reads (7%) | called by muse, mutect2
- SULF2 | c.387G>A p.V129= | Silent (SNP) | VAF 24/650 reads (4%) | called by muse, mutect2
- TAAR8 | c.666A>T p.I222= | Silent (SNP) | VAF 20/320 reads (6%) | called by muse, mutect2
- TMEM266 | c.466C>A p.R156= | Silent (SNP) | VAF 28/406 reads (7%) | called by muse, mutect2
- UGT1A6 | c.1366C>T p.L456= | Silent (SNP) | VAF 28/596 reads (5%) | catalogued as rs767264478; called by muse, mutect2
- UNC13A | c.1587C>T p.N529= | Silent (SNP) | VAF 22/667 reads (3%) | called by muse, mutect2
- ZFHX4 | c.6240C>A p.S2080= | Silent (SNP) | VAF 52/519 reads (10%) | catalogued as COSV51483245; called by muse, mutect2, varscan2
- ZNF467 | c.348G>C p.S116= | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as rs530667868; called by muse, mutect2
- ZXDA | c.471C>T p.P157= | Silent (SNP) | VAF 39/373 reads (10%) | called by muse, mutect2, varscan2
- ADAM6 | n.855C>T | RNA (SNP) | VAF 74/724 reads (10%) | catalogued as rs1473691731; called by muse, mutect2
- AL353804.4 | chrX:73820819 C>A | 3'Flank (SNP) | VAF 33/278 reads (12%) | catalogued as rs1404395383; called by muse, mutect2, varscan2
- C20orf204 | c.*68C>T | 3'UTR (SNP) | VAF 33/381 reads (9%) | called by muse, mutect2
- CMTM1 | c.240+1077G>A | Intron (SNP) | VAF 19/463 reads (4%) | called by muse, mutect2
- COL4A3 | c.-53C>G | 5'UTR (SNP) | VAF 50/1050 reads (5%) | called by muse, mutect2
- CYBA | c.287+25C>G | Intron (SNP) | VAF 25/372 reads (7%) | catalogued as rs760119415; called by muse, mutect2
- FBRS | c.-56C>T | 5'UTR (SNP) | VAF 30/426 reads (7%) | called by muse, mutect2
- GRM7 | c.2698+10928C>G | Intron (SNP) | VAF 18/322 reads (6%) | called by muse, mutect2
- GUSB | c.1066-30C>T | Intron (SNP) | VAF 62/648 reads (10%) | called by muse, mutect2
- LHX1 | chr17:36937153 C>G | 5'Flank (SNP) | VAF 15/326 reads (5%) | called by muse, mutect2
- LINC00602 | n.1265G>A | RNA (SNP) | VAF 30/536 reads (6%) | called by muse, mutect2
- LINC01100 | n.382C>T | RNA (SNP) | VAF 70/621 reads (11%) | catalogued as rs1560133958; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85790C>A | Intron (SNP) | VAF 75/1647 reads (5%) | catalogued as COSV72283651, COSV72283998; called by muse, mutect2
- MEG3 | n.1221G>T | RNA (SNP) | VAF 46/530 reads (9%) | called by muse, mutect2
- MGAM | c.4618+13389A>T | Intron (SNP) | VAF 60/624 reads (10%) | called by muse, mutect2
- MMP9 | c.1901+13G>T | Intron (SNP) | VAF 16/180 reads (9%) | called by muse, mutect2
- MROH1 | c.948+164G>A | Intron (SNP) | VAF 53/448 reads (12%) | called by muse, mutect2, varscan2
- NBPF25P | n.864C>A | RNA (SNP) | VAF 150/1932 reads (8%) | called by muse, mutect2
- NBPF25P | n.863C>A | RNA (SNP) | VAF 154/1940 reads (8%) | called by muse, mutect2
- NDUFB8 | c.469-137C>T | Intron (SNP) | VAF 31/388 reads (8%) | called by muse, mutect2
- PPP1R7 | c.52+929C>T | Intron (SNP) | VAF 38/436 reads (9%) | catalogued as rs902478855; called by muse, mutect2
- PTPN3 | c.2382+36G>C | Intron (SNP) | VAF 42/672 reads (6%) | called by muse, mutect2
- RAB18 | c.*809C>A | 3'UTR (SNP) | VAF 12/262 reads (5%) | called by muse, mutect2
- RAE1 | c.1020+94G>C | Intron (SNP) | VAF 54/734 reads (7%) | called by muse, mutect2
- RGS4 | chr1:163068966 G>T | 5'Flank (SNP) | VAF 50/687 reads (7%) | called by muse, mutect2
- SLC34A1 | c.*7G>A | 3'UTR (SNP) | VAF 32/594 reads (5%) | catalogued as rs766163401, COSV99499647; called by muse, mutect2
- STON1 | chr2:48530095 C>T | 5'Flank (SNP) | VAF 10/107 reads (9%) | called by muse, mutect2
- TMEM135 | c.*4815C>T | 3'UTR (SNP) | VAF 52/570 reads (9%) | called by muse, mutect2
- TMPRSS13 | c.*139G>T | 3'UTR (SNP) | VAF 37/562 reads (7%) | called by muse, mutect2
- VNN3 | c.*505A>G | 3'UTR (SNP) | VAF 85/810 reads (10%) | called by muse, mutect2, varscan2
- ZIK1 | c.33+14C>T | Intron (SNP) | VAF 34/479 reads (7%) | called by muse, mutect2
